Somatic mutation profile of tumor specimen TCGA-A6-6650-01A (aliquot TCGA-A6-6650-01A-11D-1771-10) from TCGA case TCGA-A6-6650, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 69.9 years (25,516 days).
Specimen TCGA-A6-6650-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b426fef-8211-48d7-a79d-1e5ff696cef6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-6650-10A (Blood Derived Normal), aliquot TCGA-A6-6650-10A-01D-1771-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58b88793-688f-4200-90ff-764b12e59c6b

The open-access MAF lists 132 somatic variants for this specimen: 105 protein-altering or splice-affecting, 27 silent.
By variant classification: Missense Mutation 91, Silent 27, Frame Shift Del 5, Frame Shift Ins 2, Splice Site 2, Nonsense Mutation 2, Nonstop Mutation 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPOX | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 80/195 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1374394802, CM970392, COSV51637936; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GFM1 | c.776A>G p.N259S | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as rs375512235, COSV51834894; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 84/177 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 34/39 reads (87%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCC10 | c.3268C>T p.R1090W (on ENST00000372530 / NM_001198934.2; = p.R1062W on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs187313814; called by muse, mutect2, varscan2
- ACTL9 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 33/52 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555753423, COSV61006777; called by muse, mutect2, varscan2
- AMPH | c.1217C>A p.P406H | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as COSV100343959, COSV57751863; called by muse, mutect2
- APC | c.4224_4225insATGAA p.P1409Mfs*8 | Frame Shift Ins (INS) | VAF 40/114 reads (35%) | catalogued as COSV57368171; called by mutect2, pindel, varscan2
- APOBR | c.1250A>G p.K417R (on ENST00000431282; = p.K426R on NM_018690.4) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as rs779351543, COSV60493011; called by muse, mutect2, varscan2
- ARMC4 | c.2804A>C p.N935T | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.297); catalogued as COSV59463724; called by muse, mutect2, varscan2
- B3GALT5 | c.823G>A p.V275I | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs766898271, COSV58200039; called by muse, mutect2, varscan2
- BCHE | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.12); catalogued as COSV100012005, COSV52253121; called by muse, mutect2, varscan2
- BIRC6 | c.10796C>T p.A3599V | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as COSV70203882; called by muse, mutect2, varscan2
- BRINP1 | c.578A>C p.K193T | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV56309272; called by muse, mutect2, varscan2
- CCDC157 | c.256C>A p.L86M | Missense Mutation (SNP) | VAF 38/48 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57841389; called by muse, mutect2, varscan2
- CCDC73 | c.2420C>A p.S807Y | Missense Mutation (SNP) | VAF 60/201 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); catalogued as COSV58802636; called by muse, mutect2, varscan2
- CDC42BPG | c.4267C>T p.R1423C | Missense Mutation (SNP) | VAF 29/38 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV61348659; called by muse, mutect2, varscan2
- CDHR3 | c.904G>A p.A302T | Missense Mutation (SNP) | VAF 64/198 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as rs923289068, COSV58420327; called by muse, mutect2, varscan2
- CERS4 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.071); catalogued as rs200803317, COSV52165519; called by muse, mutect2, varscan2
- CNTNAP5 | c.2344C>T p.R782C | Missense Mutation (SNP) | VAF 57/104 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs1455891898, COSV70476949; called by muse, mutect2, varscan2
- COL12A1 | c.8527T>G p.F2843V | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.848); catalogued as COSV59403952; called by muse, mutect2, varscan2
- CRMP1 | c.1565C>T p.S522L | Missense Mutation (SNP) | VAF 87/151 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.296); catalogued as rs187171314, COSV61478219; called by muse, mutect2, varscan2
- CYP51A1 | c.1152G>T p.M384I | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.083); catalogued as COSV50153261; called by muse, mutect2, varscan2
- DAPK1 | c.2159G>A p.R720Q | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.968); catalogued as COSV63790431; called by muse, mutect2, varscan2
- DDIT4L | c.259A>G p.R87G | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1445763095, COSV56767887; called by muse, mutect2, varscan2
- DNAH10 | c.2653G>A p.D885N (on ENST00000409039; = p.D824N on NM_207437.3) | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.739); catalogued as rs776514851, COSV68989002, COSV68991354; called by muse, mutect2, varscan2
- EEPD1 | c.812G>C p.C271S | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54201940; called by muse, mutect2
- ERBB4 | c.1233G>A p.M411I | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV53566957; called by muse, mutect2
- ESYT2 | c.1113T>G p.S371R (on ENST00000613624; = p.S295R on NM_020728.3) | Missense Mutation (SNP) | VAF 64/115 reads (56%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.667); catalogued as COSV51754987; called by muse, mutect2, varscan2
- FARS2 | c.724G>C p.D242H | Missense Mutation (SNP) | VAF 81/174 reads (47%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.935); catalogued as COSV51172611; called by muse, mutect2, varscan2
- FBN1 | c.6302C>T p.T2101M | Missense Mutation (SNP) | VAF 34/42 reads (81%) | SIFT tolerated (0.07); PolyPhen benign (0.322); catalogued as rs200816828, CM020692; ClinVar: benign / likely benign / uncertain significance; called by muse, mutect2, varscan2
- FGD1 | c.328A>T p.I110F | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.075); catalogued as COSV64309337; called by muse, mutect2, varscan2
- HCFC1 | c.4936G>A p.V1646I | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.959); catalogued as COSV60075899; called by muse, mutect2, varscan2
- HECW1 | c.1753G>A p.A585T | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs751728485, COSV67826141; called by muse, mutect2, varscan2
- HSPA2 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 32/40 reads (80%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); catalogued as COSV55970870; called by muse, mutect2, varscan2
- IGLON5 | c.606C>A p.N202K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV54537917; called by muse, mutect2
- IL31RA | c.1102G>A p.V368I | Missense Mutation (SNP) | VAF 101/255 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs779967750, COSV51683967; called by muse, mutect2, varscan2
- KCNAB2 | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1242648822, COSV51238372; called by muse, mutect2, varscan2
- KRT79 | c.13G>A p.V5I | Missense Mutation (SNP) | VAF 68/125 reads (54%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs761058456, COSV57941735; called by muse, mutect2, varscan2
- LARP4 | c.467C>G p.T156R | Missense Mutation (SNP) | VAF 60/244 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53325729; called by muse, mutect2, varscan2
- LAS1L | c.124G>A p.V42M | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as COSV56707541; called by muse, mutect2, varscan2
- MAGEB6 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.759); catalogued as rs200923993, COSV66872390, COSV66872804; called by muse, mutect2, varscan2
- MID1IP1 | c.30G>T p.Q10H | Missense Mutation (SNP) | VAF 104/198 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV61230980; called by muse, mutect2, varscan2
- MRAP2 | c.400C>A p.Q134K | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57634026; called by muse, mutect2, varscan2
- MUC16 | c.7694C>T p.T2565M | Missense Mutation (SNP) | VAF 115/186 reads (62%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs776081952, COSV67483278; called by muse, mutect2, varscan2
- NDUFS8 | c.58+2T>G p.X20_splice | Splice Site (SNP) | VAF 67/100 reads (67%) | catalogued as COSV50290263; called by muse, mutect2, varscan2
- NEK10 | c.16A>G p.K6E | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV58287727; called by muse, mutect2
- NIFK | c.403A>C p.N135H | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV53535505; called by muse, mutect2, varscan2
- NKAP | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV65056242; called by muse, mutect2, varscan2
- NRG3 | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 46/198 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV64577351; called by muse, mutect2, varscan2
- NRXN2 | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.922); catalogued as rs753732547, COSV55459296; called by muse, mutect2, varscan2
- OR2A5 | c.522C>G p.I174M | Missense Mutation (SNP) | VAF 146/280 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV68739009; called by muse, mutect2, varscan2
- OTOP3 | c.1711C>A p.L571M | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148375074; called by muse, mutect2, varscan2
- PBX2 | c.49G>A p.G17S | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs774240386, COSV66682903; called by muse, mutect2
- PCDH11X | c.2135G>A p.R712H | Missense Mutation (SNP) | VAF 86/208 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as rs758221295, COSV53492818; called by muse, varscan2
- PCDH15 | c.4733G>C p.G1578A (on ENST00000644397 / NM_001354429.2; = p.G1520A on NM_001142771.2) | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.999); catalogued as rs779719080, COSV64720867; called by muse, mutect2, varscan2
- PCDH17 | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64977399; called by muse, mutect2
- PCDH9 | c.2500G>A p.V834I | Missense Mutation (SNP) | VAF 191/286 reads (67%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.709); catalogued as rs375314712, COSV100122556, COSV60525121; called by muse, mutect2, varscan2
- PDE8B | c.357G>T p.E119D | Missense Mutation (SNP) | VAF 119/280 reads (43%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV53742774; called by muse, varscan2
- PLAC9 | c.206G>A p.G69D | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.424); catalogued as rs1433754155, COSV64840667; called by muse, mutect2, varscan2
- PLXND1 | c.3761G>A p.G1254E | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60717673; called by muse, mutect2, varscan2
- PRDM9 | c.1676G>T p.R559L | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as COSV57010925, COSV99690866; called by muse, mutect2, varscan2
- PRKAG1 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV60292552, COSV60294208; called by muse, mutect2, varscan2
- PRKDC | c.602T>C p.L201P | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100042197, COSV58060109; called by muse, mutect2, varscan2
- RAN | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 45/96 reads (47%) | catalogued as COSV54563341; called by muse, mutect2, varscan2
- RANBP6 | c.1011_1013del p.E337del | In Frame Del (DEL) | VAF 39/83 reads (47%) | catalogued as rs1252206036; called by pindel, varscan2
- RBM10 | c.2261C>A p.T754N | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV61311001; called by muse, mutect2, varscan2
- RELN | c.8683C>T p.R2895C | Missense Mutation (SNP) | VAF 92/165 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs573510714, COSV58997874, COSV59004413; called by muse, mutect2, varscan2
- RNFT1 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 183/348 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0.152); catalogued as COSV59870283; called by muse, mutect2, varscan2
- RRBP1 | c.1940A>G p.Y647C (on ENST00000377813 / NM_001365613.2; = p.Y214C on NM_004587.3) | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as rs112642316, COSV55705706; called by muse, mutect2, varscan2
- SEMA4B | c.1765G>T p.V589L | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV60175261; called by muse, mutect2, varscan2
- SEPTIN9 | c.287C>T p.S96L (on ENST00000427177 / NM_001113491.2; = p.S78L on NM_006640.4) | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.079); catalogued as rs1309991827, COSV61208599, COSV61209202; called by muse, mutect2, varscan2
- SIX2 | c.278T>A p.I93N | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV57391813; called by muse, mutect2, varscan2
- SLC25A46 | c.574C>T p.H192Y | Missense Mutation (SNP) | VAF 43/191 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV63507007; called by muse, mutect2, varscan2
- SORBS2 | c.53C>T p.S18L (on ENST00000284776 / NM_021069.5; = p.S64L on NM_003603.6) | Missense Mutation (SNP) | VAF 48/67 reads (72%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV53010533; called by muse, mutect2, varscan2
- SPATA19 | c.235C>T p.H79Y | Missense Mutation (SNP) | VAF 61/115 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as rs748936093, COSV104406994, COSV54484506; called by muse, mutect2, varscan2
- SYNPO2L | c.2293C>T p.R765W (on ENST00000394810 / NM_001114133.3; = p.R541W on NM_024875.5) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs199811689; called by muse, mutect2, varscan2
- TAS2R46 | c.866C>A p.T289N | Missense Mutation (SNP) | VAF 32/306 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV67861079; called by muse, mutect2, varscan2
- TCEAL1 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.382); catalogued as COSV65461206; called by muse, mutect2, varscan2
- THBS2 | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as rs577676627, COSV64681307; called by muse, mutect2, varscan2
- TNNI1 | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as rs931098606, COSV60190191; called by muse, mutect2, varscan2
- TTLL3 | c.2478C>A p.D826E | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as rs1042203779, COSV59615320; called by muse, mutect2
- TUBA3C | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 52/226 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.257); catalogued as rs544706766, COSV67139776; called by muse, mutect2, varscan2
- UIMC1 | c.1847del p.K616Rfs*59 | Frame Shift Del (DEL) | VAF 90/238 reads (38%) | catalogued as rs750118715; called by mutect2, pindel, varscan2
- USP9X | c.5553G>T p.E1851D | Missense Mutation (SNP) | VAF 127/249 reads (51%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV61073454; called by muse, mutect2, varscan2
- ZFP36L2 | c.1483T>A p.*495Rext*81 | Nonstop Mutation (SNP) | VAF 23/39 reads (59%) | catalogued as COSV56698705; called by muse, mutect2, varscan2
- ZMYM2 | c.2399A>G p.Y800C | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.994); catalogued as rs1371106211; called by muse, mutect2, varscan2
- ZNF536 | c.3617G>T p.G1206V | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.117); catalogued as COSV62831077, COSV62837016; called by muse, mutect2, varscan2
- ARHGEF9 | c.1240dup p.I414Nfs*18 | Frame Shift Ins (INS) | VAF 59/333 reads (18%) | called by mutect2, pindel, varscan2
- BSX | c.422T>C p.V141A | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- COL5A1 | c.2898T>A p.P966= | Splice Region (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
- DNAI4 | c.1546G>A p.G516R | Missense Mutation (SNP) | VAF 139/475 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ELMO1 | c.1053_1068del p.M351Ifs*63 | Frame Shift Del (DEL) | VAF 38/110 reads (35%) | called by mutect2, pindel, varscan2
- ETV1 | c.566A>T p.Q189L | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- HSPA6 | c.264C>A p.D88E | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- KPNA3 | c.1265T>A p.V422E | Missense Mutation (SNP) | VAF 52/199 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); called by muse, varscan2
- OR8B2 | c.511G>T p.A171S | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.533); called by muse, mutect2
- OSMR | c.706G>T p.V236L | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- PKHD1L1 | c.1735A>G p.K579E | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- PRDM12 | c.571-1G>T p.X191_splice | Splice Site (SNP) | VAF 8/32 reads (25%) | called by muse, varscan2
- SLC30A8 | c.190del p.A64Rfs*22 | Frame Shift Del (DEL) | VAF 29/62 reads (47%) | called by mutect2, pindel, varscan2
- STON2 | c.1233C>A p.S411R (on ENST00000649389 / NM_001366849.2; = p.S354R on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- TBC1D32 | c.3009_3010del p.L1005Ffs*9 | Frame Shift Del (DEL) | VAF 22/58 reads (38%) | called by mutect2, pindel, varscan2
- USP9X | c.5554C>T p.Q1852* | Nonsense Mutation (SNP) | VAF 126/251 reads (50%) | called by muse, varscan2
- WNK1 | c.849_852del p.F283Lfs*8 | Frame Shift Del (DEL) | VAF 13/62 reads (21%) | called by mutect2, pindel, varscan2
- ACTB | c.661C>T p.L221= | Silent (SNP) | VAF 39/87 reads (45%) | catalogued as COSV59320398; called by muse, mutect2, varscan2
- ANKMY1 | c.2751G>A p.K917= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as COSV56039027; called by muse, mutect2
- BBS7 | c.864C>T p.S288= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs142376157; called by muse, mutect2, varscan2
- CACNA1F | c.4002C>T p.I1334= | Silent (SNP) | VAF 91/163 reads (56%) | catalogued as COSV59906311; called by muse, mutect2, varscan2
- CSNK1A1L | c.957C>A p.A319= | Silent (SNP) | VAF 110/564 reads (20%) | catalogued as COSV65789460; called by muse, mutect2, varscan2
- DNAH1 | c.1356C>A p.I452= | Silent (SNP) | VAF 32/50 reads (64%) | catalogued as COSV70233748; called by muse, mutect2, varscan2
- HLA-DOA | c.381G>A p.Q127= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV57715305; called by muse, mutect2, varscan2
- KCNH2 | c.2292G>A p.P764= | Silent (SNP) | VAF 55/142 reads (39%) | catalogued as rs766291953, COSV51218572; called by muse, mutect2, varscan2
- LONRF3 | c.1401C>T p.C467= (on ENST00000371628 / NM_001031855.3; = p.C426= on NM_024778.5) | Silent (SNP) | VAF 98/239 reads (41%) | catalogued as rs1471680397, COSV59155627; called by muse, mutect2, varscan2
- LRWD1 | c.105C>T p.S35= | Silent (SNP) | VAF 27/83 reads (33%) | catalogued as rs781734393, COSV52961679; called by muse, mutect2, varscan2
- MAP4K1 | c.1390C>A p.R464= | Silent (SNP) | VAF 30/100 reads (30%) | catalogued as COSV67712269; called by muse, mutect2, varscan2
- MEI1 | c.276C>T p.I92= | Silent (SNP) | VAF 40/57 reads (70%) | catalogued as COSV55905949; called by muse, mutect2, varscan2
- MMGT1 | c.75G>A p.A25= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as COSV60003978; called by muse, mutect2
- MTRR | c.1509G>T p.L503= (on ENST00000264668; = p.L476= on NM_002454.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 23/186 reads (12%) | catalogued as COSV52946007, COSV52947548; called by muse, mutect2, varscan2
- PDLIM1 | c.135T>C p.C45= | Silent (SNP) | VAF 43/125 reads (34%) | catalogued as COSV61474668; called by muse, mutect2, varscan2
- PHF8 | c.1707G>T p.L569= (on ENST00000357988 / NM_001184896.1; = p.L533= on NM_015107.3) | Silent (SNP) | VAF 53/152 reads (35%) | catalogued as COSV57686168; called by muse, mutect2, varscan2
- PKHD1L1 | c.1734A>T p.I578= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV65749646; called by mutect2, varscan2
- PRKDC | c.603G>T p.L201= | Silent (SNP) | VAF 9/70 reads (13%) | called by muse, mutect2
- RBCK1 | c.225G>T p.V75= (on ENST00000356286 / NM_031229.4; = p.V33= on NM_006462.6) | Silent (SNP) | VAF 26/53 reads (49%) | catalogued as COSV62292985; called by muse, mutect2, varscan2
- ROR1 | c.2577C>G p.A859= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV64291367; called by muse, mutect2
- SCN7A | c.2778C>T p.T926= | Silent (SNP) | VAF 63/123 reads (51%) | catalogued as COSV69273742; called by muse, mutect2, varscan2
- SCUBE3 | c.897C>T p.F299= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as rs757346890, COSV51454766; called by muse, mutect2, varscan2
- SHROOM2 | c.2028C>T p.L676= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as rs1340502942, COSV66609474; called by muse, mutect2, varscan2
- SIK3 | c.3543G>A p.L1181= (on ENST00000445177 / NM_001366686.2; = p.L1139= on NM_025164.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as COSV52620887; called by muse, mutect2, varscan2
- UBR3 | c.5490C>T p.R1830= | Silent (SNP) | VAF 112/215 reads (52%) | catalogued as COSV55856940; called by muse, mutect2, varscan2
- XPO4 | c.2160A>T p.V720= | Silent (SNP) | VAF 72/161 reads (45%) | called by muse, mutect2, varscan2
- ZNF28 | c.1212T>A p.I404= | Silent (SNP) | VAF 38/80 reads (48%) | catalogued as COSV60424690; called by muse, mutect2, varscan2
